Somatic mutation profile of tumor specimen TCGA-2A-A8W3-01A (aliquot TCGA-2A-A8W3-01A-11D-A377-08) from TCGA case TCGA-2A-A8W3, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 70.0 years (25,557 days).
Specimen TCGA-2A-A8W3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b2decea-4cac-401b-a7a2-617a870cd9af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2A-A8W3-10A (Blood Derived Normal), aliquot TCGA-2A-A8W3-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37c48228-d51e-4651-afad-6a5549772a60

The open-access MAF lists 40 somatic variants for this specimen: 29 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 10, Frame Shift Ins 2, Nonsense Mutation 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8A1 | c.1247G>A p.C416Y | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV100047178; called by muse, mutect2, varscan2
- CCT4 | c.1151A>G p.K384R | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV101075355; called by muse, mutect2, varscan2
- CHRM2 | c.238T>C p.Y80H | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100281797; called by muse, mutect2, varscan2
- CNTN6 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs150393896, COSV100611726; called by muse, mutect2, varscan2
- COL5A2 | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100880714; called by muse, mutect2, varscan2
- COL6A3 | c.3308G>A p.G1103E | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99800892; called by muse, mutect2, varscan2
- DNAJC13 | c.2517T>A p.D839E | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV99607967; called by muse, mutect2, varscan2
- EPB41L3 | c.2435T>C p.I812T | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.114); catalogued as COSV100550071; called by muse, mutect2, varscan2
- EXOSC6 | c.761T>A p.V254E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV99933751; called by muse, mutect2, varscan2
- F13A1 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760818476, CM023370, COSV53554575, COSV53565368; called by muse, mutect2, varscan2
- FAM151A | c.1525T>C p.S509P | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100157088; called by muse, mutect2, varscan2
- FAM209A | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV54766567, COSV99711698; called by muse, mutect2, varscan2
- IL4R | c.763A>C p.I255L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV99405360; called by muse, mutect2, varscan2
- KCNIP2 | c.334C>T p.R112W (on ENST00000356640 / NM_173191.3; = p.R127W on NM_014591.5) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99493577; called by muse, mutect2, varscan2
- NAA15 | c.2014A>G p.I672V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV99649862; called by muse, mutect2, varscan2
- OR10C1 | c.662G>A p.R221H (on ENST00000622521; = p.R219H on NM_013941.3) | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs74711365, COSV65822383, COSV65822987; called by muse, mutect2
- PHACTR3 | c.778A>T p.S260C | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.149); catalogued as COSV100733139; called by muse, mutect2, varscan2
- PLEKHG7 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs758169319, COSV101188877; called by muse, mutect2
- SIPA1L1 | c.2405G>A p.R802Q | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as rs1161998652, COSV100666009; called by muse, mutect2, varscan2
- SLC9A5 | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs567278884, COSV55362941; called by muse, mutect2, varscan2
- SRGAP3 | c.1888G>A p.V630I | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.72); catalogued as COSV100841368; called by muse, mutect2, varscan2
- SYNE1 | c.10597C>T p.R3533C (on ENST00000367255 / NM_182961.4; = p.R3540C on NM_033071.3) | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs776816480, COSV54937774; called by muse, mutect2, varscan2
- TACC2 | c.2828C>T p.A943V | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV100553607; called by muse, mutect2, varscan2
- TUBB | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.397); catalogued as rs772090260, COSV58358177; called by muse, mutect2
- WNK1 | c.4585C>G p.L1529V (on ENST00000315939 / NM_018979.4; = p.L1282V on NM_014823.3) | Missense Mutation (SNP) | VAF 69/250 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.115); catalogued as COSV100268414; called by muse, mutect2, varscan2
- ALMS1 | c.12461dup p.R4155Efs*40 | Frame Shift Ins (INS) | VAF 4/27 reads (15%) | called by mutect2, pindel, varscan2
- IGKV2-30 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MFGE8 | c.566dup p.N189Kfs*9 | Frame Shift Ins (INS) | VAF 13/106 reads (12%) | called by mutect2, pindel, varscan2
- SUMO2 | c.36_37del p.N14Qfs*5 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by mutect2, pindel, varscan2
- ARHGEF17 | c.2991G>A p.T997= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs377593513, COSV99736619; called by muse, mutect2, varscan2
- ATP10B | c.2187C>T p.H729= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs761911543, COSV100515649, COSV59168554; called by muse, mutect2, varscan2
- ATP1A2 | c.228C>T p.N76= | Silent (SNP) | VAF 30/145 reads (21%) | catalogued as rs201540165, COSV100768001, COSV63405167; called by muse, mutect2, varscan2
- EVPL | c.2841C>G p.T947= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV101440966; called by muse, mutect2, varscan2
- PCDHA1 | c.2163G>T p.L721= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV100974450; called by muse, mutect2
- PDE6C | c.1561T>C p.L521= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs759484940, COSV101008846; called by muse, mutect2, varscan2
- PRCP | c.792C>T p.C264= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV100476373; called by muse, mutect2
- RANBP9 | c.1968A>G p.A656= | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as COSV99163616; called by muse, mutect2, varscan2
- TACR3 | c.435C>T p.Y145= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs199586035, CM104871, COSV100510883; called by muse, mutect2, varscan2
- ZNF750 | c.210A>C p.S70= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as COSV99489925; called by muse, mutect2, varscan2
- SLC28A3 | c.*2G>A | 3'UTR (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100883327; called by mutect2, varscan2
